Surgical pathology report (de-identified scan), TCGA case TCGA-DH-A7UV, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-A7UV-01A (Primary Tumor).

[page 1 of 6]
THIS IS AN ADDENDUM REPORT ****

ICD O-3
Astrocytoma, grade III
9401/3
Site 26CF
Brain, supratentorial NOS
path C71.0
Overlapping lesion of brain
C71.8

SPECIMEN(S) SUBMITTED / PROCEDURES ORDERED

- A. Brain tumor A. Frozen Section Charge
- B. Brain tumor B. Frozen Section Charge C. Infiltrated cortex
- D. Brain tumor D. Glial Fibrill. Acid Prt D. Isocitrate dehydrogenase 1
- D. P53 Protein D. KI-67, Nuclear Antigen, Mib1
- D. Phosphohistone-H3 D. 1P19q Malignant Glioma Analysis
- D. 1P19q Malignant Glioma Analysis, add x 3

CLINICAL HISTORY: This is a year old male with history of right frontotemporal mass, who is presenting for a right Stealth craniotomy for tumor.

DIAGNOSIS:

- A. Brain tumor, right frontotemporal mass, craniotomy:
Anaplastic astrocytoma (WHO Grade III)
- B. Brain tumor, right frontotemporal mass, craniotomy:
Anaplastic astrocytoma (WHO Grade III)
- C. Infiltrated cortex, right frontotemporal mass, craniotomy:
Anaplastic astrocytoma (WHO Grade III)
- D. Brain tumor, right frontotemporal mass, craniotomy:
Anaplastic astrocytoma (WHO Grade III) (see comment)

COMMENT: Highly infiltrating glioma is present in all of the above specimens. Although much of the tumor appears to show low grade histology

[page 2 of 6]
mitotic figures are present both in routine H&E stains and by immunohistochemistry study for PHH3. In addition Ki67 immunolabeling reveals focally elevated labeling indices of up to 10%.

NEUROPATHOLOGY TUMOR SUMMARY

Tumor Site

Brain / Cerebrum Right frontotemporal

Laterality: Right

Procedure

Resection

Tumor

Anaplastic astrocytoma (WHO grade III)

Ancillary studies

Glioma ancillary studies

p53 IHC: Strongly positive: 60%

IDH-1 IHC: Negative

Ki-67 (MIB-1) IHC: Positive: 10%

PHH3 IHC: Positive cells/ 10 HPF: 3

1p/ 19q: Pending

GROSS DESCRIPTION: Received the following specimen(s) in the
labeled with the patient's name and hospital #

- A. Brain tumor
- B. Brain tumor
- C. Infiltrated cortex
- D. Brain tumor

A. The specimen is received fresh, designated "Brain tumor" and

[page 3 of 6]
consists of a 0.9 x 0.9 x 0.6 cm aggregate of beige to gray-tan soft tissue with cortical gray matter and underlying subcortical white matter. A representative portion is submitted for frozen section. Frozen section diagnosis is "Portion of cortex (gray matter) and subcortical white matter, and separate fragment of neoplastic tissue" by . The frozen tissue is submitted in cassette FSA1. The remaining tissue is submitted in cassette A2.

B. The specimen is received fresh, designated "Brain tumor" and consists of a 2.2 x 1.5 x 0.9 cm portion of beige to gray-tan soft tissue with a portion of cortical gray matter and subcortical white matter. A representative portion is submitted for frozen section. Frozen section diagnosis is "Neoplasm consistent with astrocytoma, grade deferred to permanent sections" by . The frozen tissue is submitted in cassette FSB1, and the remaining tissue is submitted in cassette B2.

C. The specimen is received fresh, designated "Infiltrated cortex" and consists of a 3.5 x 2.8 x 2.4 cm portion of cortical gray matter and underlying subcortical white matter. The gray-white junction is well defined. The entire specimen is submitted in cassettes C1-C6.

D. The specimen is received fresh, designated "Brain tumor" and consists of a 2.5 x 2.0 x 1.2 cm aggregate of beige to pink-tan and myxoid-appearing soft tissue pieces. A portion is submitted to the Tumor Bank. The remaining tissue is submitted in cassettes D1-D2.

[page 4 of 6]
"I, or my qualified designee, performed the gross examination. I have personally reviewed the gross description and performed a microscopic examination on all referenced material. I have personally issued this report on the basis of the gross and microscopic findings."

Note: Test systems have been developed and their performance characteristics determined by Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Pathologist

ADDENDUM:

CHROMOSOMES 1p / 19q FISH ANALYSIS-

RESULTS

Chromosome 1p: NON-DELETED

Chromosome 19q: NON-DELETED

INTERPRETATION

There are NO deletions of chromosomes 1p and 19q in the tissue analyzed (refs 1-5).

References:

1. Cairncross JG, et al. Specific genetic predictors of

[page 5 of 6]
chemotherapeutic response and survival in patients with anaplastic oligodendrogliomas. J Natl Cancer Inst 90:1473-1479, 1998.

2. Smith JS, et al. Alterations of chromosome arms 1p and 19q as predictors of survival in oligodendrogliomas, astrocytomas, and mixed oligoastrocytomas. J Clin Oncol 18:636-45, 2000.

3. Perry A. Ancillary fish analysis for 1p and 19q status: preliminary observations in 287 gliomas and oligodendroglioma mimics. Front Biosci 8:a1-9, 2003.

4. McDonald JM, et al. The prognostic impact of histology and 1p/19q status in anaplastic oligodendroglial tumors. Cancer. 104:1468-77, 2005

5. Cairncross JG, et al. Phase III trial of chemotherapy plus radiotherapy compared with radiotherapy alone for pure and mixed anaplastic oligodendroglioma: Intergroup Radiation Therapy Oncology Group trial 9402. J Clin Oncol. 2006;24:2707-14.

Specimen

Anatomic site: Brain tumor, right frontotemporal

Test description

Reference range: 1p/ 19q: Non-deleted

A tumor is considered to have 1p or 19q deletion when the 1p probe to 1q probe ratio (1p/1q) or the 19q probe to 19p probe ratio (19q/19p) is 1.30. A tumor is considered to have chromosome 1 or 19 gain when the percentage of nuclei with ≥ 3 signals is $>20\%$. A normal 1p/1q ratio is 0.9-1.05 and a normal 19q/19 p ratio is 0.93-1.02.

The test uses two dual-probe 1p36 probe combined with a

[page 6 of 6]
control 1q probe and a 19q13.3 probe combined with a control 19p probe.

Probes are specific to the minimally deleted regions of 1p (1p36) and 19q

(19q13.3) to detect 1p and 19q deletion. The selection of tissue and the

identification of target areas on the H&E stained slide is performed by a

pathologist. The number of 1p and 19q signals in the area of interest is

scored. The testing was performed and performance characteristics of this

test were validated by the

It has not been cleared or approved by the FDA. This test is used for clinical purposes. It should

not be regarded as investigational or for research. This laboratory is

certified under the Clinical Laboratory Improvement Amendments to perform

high complexity clinical laboratory testing.

Pathologist

Criteria	hw 9/23/13	Yes	No
Dual/Synchronous Primary	NOTED		

Source: NCI Genomic Data Commons file 73494dbf-41c1-4340-8fb9-519d5c8f02b2 (TCGA-DH-A7UV.F13CB9E9-42C9-41B6-A9ED-2DFEBEF2DAE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).